Gene-level copy-number profile of tumor specimen TCGA-77-7139-01A from TCGA case TCGA-77-7139, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.5 years (20,632 days).
Specimen TCGA-77-7139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.69558a9a-259e-43c8-b89a-72c5496cc081.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7139-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6455152-6a4b-43d8-bdde-7fe57100fb1c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 139; copy number 2: 20,627; copy number 3: 22,304; copy number 4: 11,359; copy number 5: 1,389; copy number 6: 2,415; copy number 7: 196; copy number 8: 1,275; copy number 9: 18; copy number 10: 80; copy number 20: 3; copy number 40: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7139-01A-11D-2041-01): tumor purity 0.72, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:177,022,696–177,098,144, 3 genes: ZNF346, ZNF346-IT1, FGFR4.
- chr5:179,377,505–179,385,992, 3 genes: AC109479.3, AC109479.1, AC109479.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,574 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,852,020–49,451,896, 51 genes, copy number 7–40: AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P.
- chr2:51,032,601–58,159,920, 84 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:67,796,054–68,655,862, 18 genes, copy number 9 (within-gene range 4–9): LINC01812, FBXL12P1, C1D, AC017083.4, WDR92, PPIAP64, AC017083.3, PNO1, PPP3R1, AC017083.2, AC017083.1, CNRIP1, AC015969.1, PLEK, AC127383.1, FBXO48, APLF, AC130709.1.
- chr2:133,264,968–133,391,398, 3 genes, copy number 10: NCKAP5-AS2, RNU6-579P, RN7SKP154.
- chr3:133,490,824–198,222,513, 1,124 genes, copy number 8 (broad region; genes not listed).
- chr8:36,121,398–38,853,028, 74 genes, copy number 10 (broad region; genes not listed).
- chr11:40,114,203–41,459,773, 1 gene, copy number 8 (within-gene range 5–8): LRRC4C.
- chr11:41,122,907–45,513,802, 69 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr16:28,097,976–28,323,849, 8 genes, copy number 7: XPO6, TPRKBP2, AC136611.1, RNY1P10, GAPDHP35, AC138904.3, SBK1, AC138904.1.
- chr16:28,341,437–28,512,051, 13 genes, copy number 7: AC138904.2, NPIPB6, AC138894.3, EIF3CL, MIR6862-1, CDC37P2, AC138894.4, AC138894.2, AC138894.1, NPIPB7, CLN3, APOBR, IL27.
- chr17:69,961,568–75,575,209, 129 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 98. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
